Gene-level copy-number profile of tumor specimen TCGA-AN-A0FX-01A from TCGA case TCGA-AN-A0FX, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 52.9 years (19,309 days).
Specimen TCGA-AN-A0FX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.de299c77-a9d8-4acf-97ae-337427f27132.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AN-A0FX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/21349e65-11d4-43ec-80fa-3e88d25aa31f

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 892; copy number 2: 17,423; copy number 3: 18,553; copy number 4: 13,969; copy number 5: 5,305; copy number 6: 1,961; copy number 7: 289; copy number 8: 106; copy number 9: 440; copy number 10: 319; copy number 11: 274; copy number 12: 43; copy number 14: 215; copy number 15: 14; copy number 20: 7.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AN-A0FX-01A-11D-A036-01): tumor purity 0.5, ploidy 3.35, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,707 genes in 14 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:99,472,332–99,600,995, 1 gene, copy number 8 (within-gene range 5–8): LINC01708.
- chr1:150,508,062–151,953,985, 92 genes, copy number 7 (within-gene range 5–7) (broad region; genes not listed).
- chr1:241,357,343–241,484,995, 3 genes, copy number 7: AL359764.1, AL359764.2, AL359764.3.
- chr2:38,814–10,090,319, 156 genes, copy number 7 (broad region; genes not listed).
- chr3:115,413,476–115,721,490, 4 genes, copy number 7 (within-gene range 5–7): AC026341.2, AC026341.3, GAP43, AC092468.1.
- chr3:115,837,870–115,838,159, 1 gene, copy number 7: RN7SL815P.
- chr3:124,080,023–124,726,325, 1 gene, copy number 7 (within-gene range 5–7): KALRN.
- chr3:124,374,332–125,595,497, 26 genes, copy number 7: MIR6083, RNU6-143P, AC022336.2, UMPS, MIR544B, AC022336.1, ITGB5, ITGB5-AS1, AC022336.3, 7SK, ENO1P3, MUC13, HEG1, RNA5SP137, AC117488.1, SLC12A8, RNU6-230P, MIR5092, ZNF148, DUTP1, DNAJB6P7, RNU6-232P, SNX4, Y_RNA, Y_RNA, OSBPL11.
- chr5:9,363,275–25,911,234, 226 genes, copy number 8–10 (broad region; genes not listed).
- chr5:42,188,266–43,525,310, 39 genes, copy number 8 (within-gene range 6–8): AC108099.1, GHR, SERBP1P6, AC093225.1, AC113368.1, CCDC152, SELENOP, AC008945.1, AC008945.2, PPIAP77, PRELID3BP4, PRELID3BP5, PRELID3BP6, PRELID3BP7, AC008875.3, AC008875.2, AC008875.1, AC025171.1, AC025171.3, AC025171.5, ANXA2R, AC025171.2, AC025171.4, ZNF131, AC106800.3, NIM1K, AC106800.1, AC106800.2, TUBAP14, HMGCS1, AC114947.2, AC114947.1, CCL28, TMEM267, AC114956.2, C5orf34, EEF1A1P19, C5orf34-AS1, AC114956.1.
- chr8:73,290,242–73,441,526, 6 genes, copy number 7: RPL7, RDH10, RDH10-AS1, AC111149.1, AC111149.2, STAU2-AS1.
- chr8:97,624,203–145,066,685, 761 genes, copy number 9–20 (broad region; genes not listed).
- chr9:86,414,201–87,085,151, 10 genes, copy number 9 (within-gene range 5–9): AL158828.1, RNU2-36P, AL353613.1, LINC02834, AL159996.1, GAS1, GAS1RR, AL513318.1, CDC20P1, NFYCP2.
- chr13:87,765,752–114,337,626, 381 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 892. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
